CCDI case PBCGWZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/70a74b01-4138-4dc2-92ed-027d71a2b3ad

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 8.4 years (3,064 days).

Biospecimens (3 samples)
- Samples 0DRSRW, 0DRSTZ (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRSSC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
